Somatic mutation profile of tumor specimen TCGA-B5-A11M-01A (aliquot TCGA-B5-A11M-01A-11D-A122-09) from TCGA case TCGA-B5-A11M, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 44.0 years (16,063 days).
Specimen TCGA-B5-A11M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e205e25-bbf8-4e69-b0e7-485e4b210b41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11M-10A (Blood Derived Normal), aliquot TCGA-B5-A11M-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1581a54f-f071-4a2d-b7f3-3b8e4cad23ec

The open-access MAF lists 32 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 5, Nonsense Mutation 3, Frame Shift Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 50/292 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3145G>C p.G1049R | Missense Mutation (SNP) | VAF 15/83 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as rs121913277, CM126700, COSV55874453, COSV55878564, COSV55919873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 68/207 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782603, CM109590, CM110122, CM132268, COSV100910106, COSV64289126, COSV64290825; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADSL | c.352A>G p.N118D | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV53407556; called by muse, mutect2, varscan2
- ARID1A | c.5432del p.K1811Sfs*4 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as COSV61373764; called by mutect2, pindel, varscan2
- ASF1B | c.402G>A p.Q134= | Splice Region (SNP) | VAF 22/151 reads (15%) | catalogued as COSV54616049; called by muse, mutect2, varscan2
- C17orf78 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1001933226; called by muse, mutect2
- CCAR1 | c.1951C>T p.R651* | Nonsense Mutation (SNP) | VAF 28/154 reads (18%) | catalogued as COSV56267144; called by muse, mutect2, varscan2
- CIR1 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 66/357 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs144271294, COSV59595893; called by muse, mutect2, varscan2
- CLCN3 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV61626908; called by muse, mutect2, varscan2
- CLPX | c.1138G>T p.V380F | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55644251; called by muse, mutect2, varscan2
- CRISP1 | c.479C>A p.S160Y | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV59993447; called by muse, mutect2, varscan2
- CSGALNACT2 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 61/315 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV65675496; called by muse, mutect2, varscan2
- CTSA | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs139920208; called by muse, mutect2, varscan2
- DHRSX | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1418375528, COSV58132950; called by muse, mutect2, varscan2
- DMD | c.9346C>A p.Q3116K | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398124093, CM013380, COSV58907076; called by muse, mutect2, varscan2
- ESRRG | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs184409476; called by muse, mutect2, varscan2
- ITK | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.096); catalogued as COSV68435315; called by muse, mutect2, varscan2
- LRP6 | c.3916C>T p.R1306* | Nonsense Mutation (SNP) | VAF 18/120 reads (15%) | catalogued as rs1252291809, COSV53786753; called by muse, mutect2, varscan2
- MLPH | c.1496C>T p.T499M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs373395826; called by mutect2, varscan2
- MSANTD1 | c.431C>A p.P144Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV70873242, COSV70873285; called by muse, mutect2, varscan2
- SCAF11 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 26/167 reads (16%) | catalogued as rs1345841174, COSV65476307; called by muse, mutect2, varscan2
- SLC1A6 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs768996035, COSV55669920; called by muse, mutect2, varscan2
- STRN4 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs748689271, COSV54418172; called by muse, mutect2, varscan2
- TOP3B | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs780826549, COSV64117121; called by muse, mutect2, varscan2
- ZFAND2B | c.358C>G p.R120G | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs535919706, COSV54695533; called by muse, mutect2, varscan2
- BRINP3 | c.441C>A p.L147= | Silent (SNP) | VAF 24/125 reads (19%) | catalogued as COSV66522490; called by muse, mutect2, varscan2
- CIT | c.4542A>G p.A1514= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs766351202, COSV55867267; called by muse, mutect2, varscan2
- DCHS1 | c.7035C>T p.Y2345= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs759063650, COSV55034703; called by muse, mutect2, varscan2
- STAG3 | c.2934C>T p.L978= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as rs753133633, COSV57929968; called by muse, mutect2, varscan2
- TASOR2 | c.2988C>T p.Y996= | Silent (SNP) | VAF 40/181 reads (22%) | catalogued as rs545198118, COSV60166874, COSV60168331; called by muse, mutect2, varscan2
- DCHS2 | n.2438C>A | RNA (SNP) | VAF 18/86 reads (21%) | catalogued as COSV59724839; called by muse, mutect2, varscan2
